Surgical pathology report (de-identified scan), TCGA case TCGA-CM-4752, project TCGA-COAD (Colon Adenocarcinoma), tissue source site MSKCC, specimen TCGA-CM-4752-01A (Primary Tumor).

[page 1 of 2]
TCGA-CM-4752

Clinical Diagnosis & History:
Right-sided colon cancer.

Specimens Submitted:
1: SP: Right colon

DIAGNOSIS:

1. COLON; RIGHT HEMICOLECTOMY:
- TUMOR TYPE: ADENOCARCINOMA.
- HISTOLOGIC GRADE: MODERATELY DIFFERENTIATED.
- TUMOR LOCATION: ASCENDING COLON.
- TUMOR SIZE: LENGTH IS 4.0 CM, WIDTH IS 5.4 CM.
- GROSS CONFIGURATION: ULCERATING INFILTRATIVE.
- TUMOR INVASION: INVASION INTO SUBSEROA.
- GROSS TUMOR PERFORATION: NOT IDENTIFIED.
- SEROSAL INVOLVEMENT: NOT IDENTIFIED.
- VASCULAR INVASION: NOT IDENTIFIED.
- PERINEURAL INVASION: IDENTIFIED.
- SURGICAL MARGINS (FOR COLONIC TUMORS): FREE OF TUMOR.
- NON-NEOPLASTIC BOWEL: UNREMARKABLE.
- THE PATHOLOGIC STAGE IS [REDACTED] PT3.
- LYMPH NODES: NUMBER WITH METASTASES: 0; NUMBER EXAMINED: 23.
- THE PATHOLOGIC STAGE IS [REDACTED]: pN0.
- APPENDIX AND OMENTUM WITH NO SIGNIFICANT PATHOLOGIC CHANGE.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

- 1) The specimen is received fresh, labeled "Right colon" and consists of a

** Continued on next page **

[page 2 of 2]
----- Page 2 of 2
segment of terminal ileum, cecum with attached appendix and ascending colon.
The terminal ileum measures 8 cm in length and 3.4 cm in circumference at the proximal resected margin. The remaining colon measures 34 cm in length with a circumference of 8 cm at the distal resected margin. The attached appendix measures 7.2 cm in length and averages 0.6 cm in diameter. The appendiceal and intestinal serosa is pink tan and smooth. Focally hemorrhagic lobulated yellow tan adipose tissue spans the length of the specimen measuring up to 5 cm in thickness. The specimen is opened to reveal a mass lesion measuring 4 cm in length and 5.4 cm in width. Sectioning shows that the tumor invades into the pericolic fat. The depth of invasion is 0.5 cm grossly. The lesion is 5 cm from the distal margin. There is attached omental fat measuring 25 x 12 x 1.5 cm. It is grossly unremarkable. The remaining mucosa is unremarkable. Multiple lymph nodes are identified in the attached adipose tissue and are submitted. Representative sections of the specimen are submitted for permanent sections and for TPS.

Summary of sections:

PM-- proximal margin shave

DM -- distal margin shave

M-- mass

A -- appendix representative sections

RS--representative sections

O- omentum representative sections

LN-- lymph nodes

Summary of Sections:

Part 1: SP: Right colon

Block	Sect. Site	PCs
1	A	1
4	BLN	8
1	DM	1
6	LN	18
4	M	4
2	O	2
1	PM	1
1	RS	1

** End of Report **

Source: NCI Genomic Data Commons file d3cead95-5c9f-4fea-ad3c-fc2eb031f2eb (TCGA-CM-4752.121AE2CB-7FD4-4343-80CE-77FD001B1787.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).